Somatic mutation profile of tumor specimen TCGA-96-8170-01A (aliquot TCGA-96-8170-01A-11D-2293-08) from TCGA case TCGA-96-8170, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.4 years (27,558 days).
Specimen TCGA-96-8170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d0fc4e9-d39b-4636-baf0-b00f2c24c850.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-96-8170-10A (Blood Derived Normal), aliquot TCGA-96-8170-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22f007c3-6c38-44fa-aaed-a33f7671ad47

The open-access MAF lists 258 somatic variants for this specimen: 194 protein-altering or splice-affecting, 54 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 54, Nonsense Mutation 12, RNA 5, Frame Shift Ins 4, Frame Shift Del 3, Intron 2, Translation Start Site 2, Splice Site 2, 5'UTR 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT4 | c.667G>C p.G223R | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100412825; called by muse, mutect2
- ACP7 | c.973G>T p.G325* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100488470; called by mutect2, varscan2
- ACP7 | c.973+1G>T p.X325_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100488476; called by muse, mutect2, varscan2
- ACTR3 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99603489; called by mutect2, varscan2
- ADGRB3 | c.2886G>T p.E962D | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99484434; called by muse, mutect2, varscan2
- ADGRG2 | c.378C>G p.I126M (on ENST00000379869 / NM_001079858.3; = p.I123M on NM_005756.4) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100492108; called by muse, mutect2
- AFF2 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100649605; called by muse, mutect2, varscan2
- AKAP13 | c.6041A>T p.K2014M (on ENST00000394518 / NM_007200.5; = p.K2018M on NM_006738.6) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV100773425, COSV63447441; called by muse, mutect2, varscan2
- APBA2 | c.978G>C p.R326S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.658); catalogued as COSV101258142, COSV67104425; called by muse, mutect2, varscan2
- APH1B | c.163A>T p.M55L | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs966653733, COSV99971494; called by muse, mutect2, varscan2
- ARHGAP30 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100920188; called by muse, mutect2, varscan2
- BCL9L | c.4448G>A p.S1483N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.431); catalogued as COSV99419000; called by muse, mutect2, varscan2
- BOC | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 25/383 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1276405896, COSV99848457; called by muse, mutect2
- BPTF | c.5047C>G p.L1683V | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV100074582; called by muse, mutect2
- BTBD2 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV99724677; called by muse, mutect2
- C10orf71 | c.1162A>T p.K388* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100109987; called by muse, mutect2, varscan2
- C10orf88 | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV100925007; called by muse, mutect2, varscan2
- C19orf57 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV100694667; called by muse, mutect2, varscan2
- C3orf20 | c.101A>C p.N34T | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV99513685; called by muse, mutect2, varscan2
- CARD10 | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99324808; called by muse, mutect2, varscan2
- CATSPER1 | c.2317G>C p.A773P | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV100375798; called by muse, mutect2, varscan2
- CCDC136 | c.2384G>C p.S795T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs774877982, COSV99922459; called by muse, mutect2, varscan2
- CCDC63 | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV100370285; called by muse, mutect2, varscan2
- CCT6B | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100030563; called by muse, mutect2, varscan2
- CD163L1 | c.1403G>C p.C468S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100549908, COSV58025973; called by muse, mutect2, varscan2
- CDC20 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV100196399; called by muse, mutect2
- CDC20B | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs775191808, COSV99696734; called by muse, mutect2, varscan2
- CDK7 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV99841632; called by muse, mutect2, varscan2
- CDKL5 | c.2435G>A p.S812N | Missense Mutation (SNP) | VAF 62/314 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV101184202; called by muse, mutect2, varscan2
- CENPJ | c.1302C>G p.D434E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101121491; called by muse, mutect2, varscan2
- CHRM5 | c.1505T>A p.F502Y | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101271891; called by muse, mutect2, varscan2
- CLEC3B | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374425404; called by muse, mutect2, varscan2
- CLPB | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as rs964256040, COSV99577834; called by muse, mutect2, varscan2
- CLTC | c.2644A>G p.I882V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV99291983; called by muse, mutect2, varscan2
- CNGB3 | c.2302C>T p.H768Y | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV60693712; called by muse, mutect2, varscan2
- COBL | c.623A>T p.E208V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99472026; called by muse, mutect2, varscan2
- COL8A1 | c.90C>A p.Y30* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as COSV99657467; called by muse, mutect2, varscan2
- CSMD3 | c.10850C>G p.S3617* (on ENST00000297405 / NM_001363185.1; = p.S3448* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 7/110 reads (6%) | catalogued as COSV52260847, COSV99830282; called by muse, mutect2
- CSMD3 | c.3637C>G p.R1213G (on ENST00000297405 / NM_001363185.1; = p.R1109G on NM_052900.3) | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52288397, COSV99830283; called by muse, mutect2, varscan2
- CST9L | c.408C>A p.S136R | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100980850; called by muse, mutect2, varscan2
- DCAF8L1 | c.996T>A p.D332E | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101491432; called by muse, mutect2, varscan2
- DCSTAMP | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV99886368; called by muse, mutect2
- DNAH7 | c.4719C>G p.I1573M | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as COSV100414582; called by muse, mutect2
- DNHD1 | c.11570G>A p.G3857E | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1374241412, COSV99599775; called by muse, mutect2, varscan2
- DOCK4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV101455490; called by muse, mutect2, varscan2
- DOCK8 | c.3310G>C p.E1104Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101209880; called by muse, mutect2, varscan2
- DPH2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs529900643, COSV52542768; called by muse, mutect2, varscan2
- DR1 | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs764726619, COSV64725903; called by mutect2, varscan2
- EFCAB11 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as COSV99965576; called by muse, mutect2
- ERF | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.985); catalogued as rs756887571, COSV99724582; called by muse, mutect2, varscan2
- F13A1 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99342224, COSV99342661; called by muse, mutect2, varscan2
- FAM131B | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV101281783; called by muse, mutect2, varscan2
- FAM135B | c.1476G>A p.M492I | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99421737; called by muse, mutect2
- FAT1 | c.12019C>T p.P4007S | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV101499242; called by muse, mutect2, varscan2
- FCRL5 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.449); catalogued as COSV100708750, COSV62519780; called by muse, mutect2, varscan2
- FGD2 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as COSV51462629, COSV99236037; called by muse, mutect2, varscan2
- FGFR3 | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99601289; called by muse, varscan2
- FMN1 | c.3476G>A p.R1159K (on ENST00000616417 / NM_001277313.2; = p.R936K on NM_001103184.4) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV100568329; called by muse, mutect2
- FMR1NB | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 47/379 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100789525; called by muse, mutect2, varscan2
- FNBP4 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99771565; called by muse, mutect2, varscan2
- FOXK2 | c.1248C>G p.I416M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as COSV100081950; called by mutect2, varscan2
- FPGT-TNNI3K | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100598620; called by muse, mutect2, varscan2
- FRMPD1 | c.3354C>G p.N1118K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV100899511; called by muse, mutect2, varscan2
- GALP | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.64); catalogued as rs376398790; called by muse, mutect2, varscan2
- GAS8 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 37/198 reads (19%) | catalogued as COSV51946161, COSV99243883; called by muse, mutect2, varscan2
- GLI3 | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462048687, CM127567, COSV101229798; called by muse, mutect2, varscan2
- GMCL1 | c.1132A>T p.S378C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV99247638; called by muse, mutect2, varscan2
- GMDS | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV101071615; called by muse, mutect2, varscan2
- GNA15 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1396214838, COSV53585766; called by muse, varscan2
- GOLGA5 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV99370832; called by muse, mutect2
- GOLIM4 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV100462849; called by muse, mutect2, varscan2
- GRIN3A | c.1463del p.K488Rfs*28 | Frame Shift Del (DEL) | VAF 56/231 reads (24%) | catalogued as COSV99054451; called by mutect2, pindel, varscan2
- GUCY2F | c.1418G>T p.C473F | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99484759; called by muse, mutect2, varscan2
- GYS2 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99679626; called by muse, mutect2
- HEG1 | c.4090G>A p.G1364R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100229835, COSV60761255; called by muse, mutect2, varscan2
- HERC1 | c.4691A>G p.H1564R | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs562272047, COSV101496482; called by muse, mutect2, varscan2
- HNRNPH2 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as COSV99516275; called by muse, mutect2, varscan2
- HSPA6 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100554052; called by muse, mutect2
- HSPA6 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV100554056; called by muse, mutect2
- HUWE1 | c.4908C>A p.S1636R | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as COSV99471471; called by muse, mutect2, varscan2
- IGHV3-15 | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.035); catalogued as rs547870950; called by muse, mutect2, varscan2
- IMPG1 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100886294; called by muse, mutect2, varscan2
- IRF8 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51898013; called by muse, mutect2
- ITIH6 | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as rs148146291, COSV54494451; called by muse, mutect2, varscan2
- ITM2B | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as COSV101052308; called by muse, mutect2
- KARS1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100093939; called by muse, mutect2, varscan2
- KCND2 | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100474818; called by muse, mutect2, varscan2
- KCNS2 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV99750980; called by muse, mutect2, varscan2
- KIT | c.2440G>T p.A814S | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853764; called by muse, mutect2, varscan2
- KLHL4 | c.833A>G p.Q278R | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV100909367; called by muse, mutect2, varscan2
- KLK9 | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99143933; called by muse, mutect2, varscan2
- LILRB2 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 33/147 reads (22%) | catalogued as COSV100079187, COSV58743732; called by muse, mutect2, varscan2
- LILRB4 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV54408133; called by muse, mutect2, varscan2
- LPA | c.3503G>C p.C1168S | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100306520, COSV60301370; called by muse, mutect2, varscan2
- LPCAT1 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV52036747, COSV99358898; called by muse, mutect2, varscan2
- LRRC7 | c.2831G>T p.S944I (on ENST00000651989 / NM_001370785.2; = p.S911I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.182); catalogued as COSV99225709; called by muse, mutect2, varscan2
- LRRK2 | c.1085A>T p.K362M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV100109720; called by muse, mutect2, varscan2
- LUC7L2 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99692914; called by muse, mutect2, varscan2
- MAK16 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100789433; called by muse, mutect2, varscan2
- MAP1A | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55813575; called by muse, mutect2, varscan2
- MAP1B | c.1112A>G p.N371S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as rs749045605, COSV99702113; called by muse, mutect2, varscan2
- MAP2K1 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1289766973, COSV100198762, COSV61073544; called by muse, mutect2, varscan2
- MAP3K15 | c.3679+1G>T p.X1227_splice | Splice Site (SNP) | VAF 46/362 reads (13%) | catalogued as COSV100134470; called by muse, mutect2, varscan2
- MAP7D3 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100286265; called by muse, mutect2, varscan2
- MBL2 | c.380C>G p.T127S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100906307, COSV64759367; called by muse, mutect2, varscan2
- MIA2 | c.1237C>A p.H413N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV99696689; called by muse, mutect2, varscan2
- MLIP | c.496A>T p.I166F | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV99228920; called by muse, mutect2, varscan2
- MMP19 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.388); catalogued as rs1243527525, COSV100491050; called by muse, mutect2
- MRGPRX4 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100049695, COSV58591149, COSV58591716; called by muse, mutect2, varscan2
- MROH2B | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.616); catalogued as COSV101270616; called by muse, mutect2, varscan2
- MSN | c.1313A>T p.K438M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV100814160; called by muse, mutect2
- MYBPC2 | c.1925C>A p.P642Q | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100731731, COSV63098996, COSV63099886; called by muse, mutect2, varscan2
- NDUFA13 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV99389002; called by muse, mutect2, varscan2
- NEB | c.5974C>T p.L1992F | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1310185071, COSV99419049; called by muse, mutect2, varscan2
- NEK4 | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV99237440; called by muse, mutect2, varscan2
- NLRC5 | c.2842C>A p.P948T | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.07); catalogued as COSV99346857; called by muse, mutect2, varscan2
- NLRP13 | c.1984G>C p.D662H | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV100738134; called by muse, mutect2
- NLRP8 | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as COSV99405045; called by muse, mutect2
- NME9 | c.404C>T p.S135F (on ENST00000333911 / NM_001349024.2; = p.S74F on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV100444660; called by muse, mutect2
- NMNAT1 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101020399; called by muse, mutect2, varscan2
- NRROS | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV100145435; called by muse, mutect2, varscan2
- NUFIP1 | c.1258A>T p.S420C | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100997987; called by muse, mutect2, varscan2
- NXPE3 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99839870; called by muse, mutect2, varscan2
- ODF2 | c.433A>G p.K145E (on ENST00000434106 / NM_153433.2; = p.K121E on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV100654516; called by muse, mutect2, varscan2
- OR2M3 | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101513414; called by muse, mutect2, varscan2
- OR2T4 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV100822440, COSV63543621, COSV63544272; called by muse, mutect2, varscan2
- OR4C16 | c.335T>A p.I112N | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs143747626; called by muse, mutect2, varscan2
- OR56B4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs866651182, COSV57204093; called by muse, mutect2, varscan2
- OR5D16 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs1445956731, COSV101003903; called by muse, mutect2, varscan2
- OR6T1 | c.951G>T p.R317S | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV100189845; called by muse, mutect2, varscan2
- PACRGL | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99763993; called by muse, mutect2, varscan2
- PAGE3 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs758824961, COSV100891978; called by muse, mutect2, varscan2
- PCDH15 | c.3343G>T p.V1115F | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.937); catalogued as COSV100218325; called by muse, mutect2, varscan2
- PCDHB14 | c.1691C>A p.P564Q | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53391746, COSV99505604; called by muse, mutect2
- PCYT1B | c.58del p.R20Afs*4 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | catalogued as COSV64776398; called by mutect2, pindel, varscan2
- PHF6 | c.784G>C p.D262H (on ENST00000332070 / NM_032458.3; = p.D263H on NM_032335.3) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); catalogued as COSV100136266, COSV100136354; called by muse, mutect2, varscan2
- PJVK | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.3); catalogued as rs1261302190, COSV100359525; called by muse, mutect2
- PKHD1 | c.11246C>A p.P3749H | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100944131; called by muse, mutect2, varscan2
- PLEKHG3 | c.3050G>T p.G1017V (on ENST00000394691; = p.G1073V on NM_001308147.2) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1422051852; called by muse, mutect2
- PLEKHG7 | c.1714A>T p.K572* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100760077; called by muse, mutect2
- PPP1R21 | c.926C>G p.S309C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV99681869; called by muse, mutect2, varscan2
- PPP2R5C | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159304; called by muse, mutect2, varscan2
- PPP4R3A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1243118522, COSV100465886; called by muse, mutect2, varscan2
- PREX2 | c.3454C>T p.H1152Y | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV55775797, COSV99906255; called by muse, mutect2
- PRLR | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1287914462, COSV99184289; called by muse, mutect2, varscan2
- PTPRO | c.2654C>G p.T885S | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV99840207; called by muse, mutect2, varscan2
- RAB39A | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); catalogued as COSV100269148, COSV57694721; called by muse, mutect2, varscan2
- RBM10 | c.1637G>T p.S546I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV100237596; called by muse, mutect2, varscan2
- RBM15 | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs1315022815, COSV100873419; called by muse, mutect2, varscan2
- RECQL | c.665A>G p.H222R | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100131235; called by muse, mutect2, varscan2
- RICTOR | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV99704683; called by muse, mutect2, varscan2
- RIPK2 | c.1063A>T p.S355C | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as COSV55131866, COSV99609824; called by muse, mutect2, varscan2
- RNLS | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.12); catalogued as COSV100076408; called by muse, mutect2, varscan2
- RYR2 | c.10517G>T p.R3506L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV100769225, COSV63670201; called by muse, mutect2, varscan2
- SAMD3 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100148167; called by muse, mutect2, varscan2
- SEL1L2 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); catalogued as COSV99429586; called by muse, mutect2, varscan2
- SEMA7A | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV99984690, COSV99984921; called by muse, mutect2, varscan2
- SH3D21 | c.1625C>T p.S542F (on ENST00000453908 / NM_001162530.2; = p.S431F on NM_024676.5) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99583990; called by muse, mutect2, varscan2
- SHANK3 | c.962A>G p.Q321R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99436676; called by muse, mutect2, varscan2
- SI | c.5264C>G p.T1755S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV100014853, COSV52269017; called by muse, mutect2, varscan2
- SLC25A46 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.069); catalogued as COSV100582563; called by muse, mutect2
- SLC36A1 | c.810A>T p.E270D | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99695478; called by muse, mutect2, varscan2
- SLC44A4 | c.1949T>C p.V650A | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99998819; called by muse, mutect2, varscan2
- SLC46A1 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99134956; called by muse, mutect2
- SLC8A1 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100245488; called by muse, mutect2, varscan2
- SLCO1C1 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99858819; called by muse, mutect2, varscan2
- SOX6 | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.753); catalogued as COSV100321735; called by muse, mutect2, varscan2
- SPAG17 | c.3493G>A p.V1165M | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV100308204, COSV100308611; called by muse, mutect2, varscan2
- SWT1 | c.1240G>C p.G414R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833187, COSV100833234; called by muse, mutect2, varscan2
- TAAR1 | c.674G>C p.S225T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV99257529; called by muse, mutect2, varscan2
- TBXT | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV99752297; called by muse, mutect2
- TENM4 | c.3512G>A p.W1171* | Nonsense Mutation (SNP) | VAF 67/430 reads (16%) | catalogued as COSV53651944, COSV99572927; called by muse, mutect2, varscan2
- TNR | c.3668G>T p.R1223L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54900246; called by muse, mutect2, varscan2
- TP53 | c.158_159insT p.W53Cfs*4 | Frame Shift Ins (INS) | VAF 71/355 reads (20%) | catalogued as COSV99390761; called by mutect2, pindel, varscan2
- TRIM9 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV100031018; called by muse, mutect2
- TTN | c.22213C>T p.Q7405* (on ENST00000591111; = p.Q6478* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100625406, COSV60259449; called by muse, mutect2, varscan2
- TUBAL3 | c.249T>C p.D83= | Splice Region (SNP) | VAF 33/184 reads (18%) | catalogued as COSV100990504; called by muse, mutect2, varscan2
- TULP1 | c.1522C>A p.R508S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751036771, COSV100004024, COSV57692382; called by muse, mutect2, varscan2
- UPF3B | c.1178T>A p.M393K (on ENST00000276201 / NM_080632.3; = p.M380K on NM_023010.3) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs1318649861, COSV99352072; called by muse, mutect2, varscan2
- WIF1 | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV99682743; called by muse, mutect2, varscan2
- WWC1 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV99514723; called by muse, mutect2
- WWC3 | c.2645C>A p.A882D | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV101081271, COSV66505621; called by muse, mutect2, varscan2
- ZBED2 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99342636; called by muse, mutect2, varscan2
- ZC3HC1 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100315687; called by muse, mutect2, varscan2
- ZNF157 | c.1426G>T p.G476W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100998473; called by muse, mutect2, varscan2
- ZNF157 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100998474; called by muse, mutect2, varscan2
- ZNF479 | c.369A>T p.L123F | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100482651, COSV100482750; called by muse, mutect2, varscan2
- ZNF750 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53959616, COSV53962745; called by muse, mutect2
- ADCY6 | c.1835G>T p.R612L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- IGKV1D-16 | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV3D-11 | c.192del p.R65Gfs*34 | Frame Shift Del (DEL) | VAF 24/137 reads (18%) | called by mutect2, pindel, varscan2
- PIK3IP1 | c.637_638insAA p.M213Kfs*84 | Frame Shift Ins (INS) | VAF 26/123 reads (21%) | called by mutect2, pindel, varscan2
- PTEN | c.601_602insGAAATGTTTG p.E201Gfs*4 | Frame Shift Ins (INS) | VAF 27/184 reads (15%) | called by mutect2, varscan2
- STAG2 | c.2235dup p.A746Cfs*2 | Frame Shift Ins (INS) | VAF 15/139 reads (11%) | called by mutect2, pindel, varscan2
- ABLIM2 | c.450C>G p.L150= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99589396, COSV99589657; called by muse, mutect2, varscan2
- ADGRL3 | c.1530C>A p.T510= (on ENST00000506720 / NM_001322402.2; = p.T442= on NM_015236.6) | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as COSV101546967; called by muse, mutect2, varscan2
- ALK | c.2608C>T p.L870= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV101201782; called by muse, mutect2, varscan2
- AMER1 | c.2979C>A p.T993= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100365771; called by muse, mutect2, varscan2
- CACNA2D1 | c.2742A>T p.A914= (on ENST00000356253 / NM_001366867.1; = p.A902= on NM_000722.4) | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV100666363; called by muse, mutect2, varscan2
- CARMIL2 | c.1077C>G p.L359= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100576025; called by muse, mutect2, varscan2
- CHID1 | c.798G>A p.A266= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as rs375089194; called by muse, mutect2, varscan2
- DHTKD1 | c.2280A>T p.P760= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV99536261; called by muse, mutect2, varscan2
- DHX36 | c.1854T>C p.L618= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100273489; called by muse, mutect2, varscan2
- DSCAM | c.930G>T p.V310= | Silent (SNP) | VAF 19/292 reads (7%) | catalogued as COSV101259688; called by muse, mutect2
- EXTL1 | c.1530C>G p.A510= | Silent (SNP) | VAF 39/275 reads (14%) | catalogued as COSV100958518, COSV65333162; called by muse, mutect2, varscan2
- FAT4 | c.1005G>A p.G335= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV101272201; called by muse, mutect2, varscan2
- FMR1NB | c.282C>A p.S94= | Silent (SNP) | VAF 47/371 reads (13%) | catalogued as COSV100789526; called by muse, mutect2, varscan2
- GABRA2 | c.330C>A p.I110= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100734067, COSV62920193; called by muse, mutect2, varscan2
- GH2 | c.126C>A p.R42= | Silent (SNP) | VAF 57/281 reads (20%) | catalogued as rs770417030, COSV100236927; called by muse, mutect2, varscan2
- HLA-DQA2 | c.369G>T p.V123= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV100890696; called by muse, mutect2, varscan2
- HUWE1 | c.6384C>A p.T2128= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV99471464, COSV99472278; called by muse, mutect2, varscan2
- IFT172 | c.471C>T p.S157= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99561656, COSV99562124; called by muse, mutect2, varscan2
- KBTBD4 | c.1026T>C p.D342= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs147179417; called by muse, mutect2, varscan2
- KCND1 | c.1737C>A p.A579= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99501876; called by muse, mutect2
- KCNJ11 | c.696C>T p.P232= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100379035; called by muse, mutect2, varscan2
- KIF21A | c.4215A>G p.V1405= (on ENST00000361418 / NM_001378440.1; = p.V1392= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV100735384; called by muse, mutect2, varscan2
- MARS1 | c.1731G>A p.L577= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as rs773313017, COSV100007235; called by muse, mutect2, varscan2
- MNDA | c.592C>A p.R198= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100933295; called by muse, mutect2, varscan2
- MUC16 | c.26811C>T p.N8937= | Silent (SNP) | VAF 49/246 reads (20%) | catalogued as COSV101199265; called by muse, mutect2, varscan2
- NAGS | c.15G>C p.L5= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV53227940, COSV99517827; called by muse, mutect2
- NEMP1 | c.180G>A p.K60= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as COSV100272117; called by muse, mutect2, varscan2
- NUAK1 | c.1074T>C p.S358= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV99776847; called by muse, mutect2, varscan2
- OR1L4 | c.222C>T p.F74= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99413827; called by muse, mutect2, varscan2
- OR3A1 | c.315C>T p.F105= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100041624, COSV100041728; called by muse, mutect2, varscan2
- OR4K1 | c.420C>G p.L140= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV99578819; called by muse, mutect2, varscan2
- OR5F1 | c.438C>A p.A146= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV53545224, COSV99558526; called by muse, mutect2, varscan2
- OR9G4 | c.186C>T p.F62= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV57250057; called by muse, mutect2, varscan2
- PADI2 | c.1893C>T p.F631= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as COSV64954687; called by muse, mutect2, varscan2
- PPP2R2C | c.1311C>A p.I437= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100160385; called by muse, mutect2, varscan2
- RO60 | c.33G>A p.L11= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV66474811; called by muse, mutect2, varscan2
- SLC22A9 | c.741C>G p.T247= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99654886; called by muse, mutect2, varscan2
- SLCO1B3 | c.381C>A p.T127= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs1003882608, COSV99681176; called by muse, mutect2, varscan2
- SPHKAP | c.1398C>A p.G466= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100763945; called by muse, mutect2, varscan2
- SPIN4 | c.306T>A p.P102= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100633335; called by muse, mutect2, varscan2
- SPTA1 | c.3546C>A p.A1182= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100934675; called by muse, mutect2, varscan2
- STPG2 | c.423A>T p.I141= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as COSV99758748; called by muse, mutect2
- TAAR6 | c.33G>T p.V11= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99256571; called by muse, varscan2
- TAAR6 | c.246T>A p.G82= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV99256572; called by muse, mutect2, varscan2
- TIE1 | c.567G>A p.S189= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs370753859, COSV100992044; called by muse, mutect2, varscan2
- TNXB | c.9678C>T p.F3226= (on ENST00000647633; = p.F2979= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs1264996067, COSV100926137; called by muse, mutect2
- WWC3 | c.2646C>A p.A882= | Silent (SNP) | VAF 46/260 reads (18%) | catalogued as COSV101081273; called by muse, mutect2, varscan2
- XKR8 | c.654G>A p.V218= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as COSV100871914; called by muse, mutect2, varscan2
- XPNPEP2 | c.666C>A p.G222= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100941194; called by muse, mutect2
- ZFP36L1 | c.822G>T p.P274= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as COSV100322584, COSV100322960; called by muse, mutect2, varscan2
- ZNF627 | c.687G>A p.G229= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100741460; called by muse, mutect2, varscan2
- ZNF668 | c.1155G>A p.V385= | Silent (SNP) | VAF 12/298 reads (4%) | catalogued as COSV100336566; called by muse, mutect2
- ZNF687 | c.3312T>A p.P1104= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99649497; called by muse, mutect2, varscan2
- ZSWIM4 | c.795G>A p.V265= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99584687; called by muse, mutect2
- CTNNA2 | c.-1C>A | 5'UTR (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100782981; called by muse, varscan2
- IL21 | c.*2G>T | 3'UTR (SNP) | VAF 11/71 reads (15%) | catalogued as rs752671868, COSV52645358; called by muse, mutect2, varscan2
- MAGEA5 | n.94A>G | RNA (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- MIR376A1 | n.46C>A | RNA (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- MIR518A2 | n.19C>T | RNA (SNP) | VAF 33/309 reads (11%) | called by muse, mutect2, varscan2
- MIR518E | n.21G>T | RNA (SNP) | VAF 25/190 reads (13%) | called by muse, mutect2, varscan2
- PDE4D | c.455+124915A>G | Intron (SNP) | VAF 44/290 reads (15%) | catalogued as rs765287869, COSV100506012; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15144G>T | Intron (SNP) | VAF 24/178 reads (13%) | catalogued as COSV101042549, COSV101043426; called by muse, mutect2, varscan2
- TAOK2 | chr16:29991380 A>T | 3'Flank (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99662941; called by muse, mutect2
- TP73-AS1 | n.1229C>G | RNA (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
